Gene-level copy-number profile of tumor specimen TCGA-AN-A0XN-01A from TCGA case TCGA-AN-A0XN, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 68.5 years (25,029 days).
Specimen TCGA-AN-A0XN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.109817fb-aa2e-4ac8-8bac-a8c6f0d93551.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AN-A0XN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1ff72926-3b7a-47fb-b773-6de7fdf24106

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 985; copy number 2: 19,944; copy number 3: 20,969; copy number 4: 7,993; copy number 5: 5,286; copy number 6: 1,424; copy number 7: 2,434; copy number 8: 372; copy number 9: 223; copy number 15: 52; copy number 16: 133; copy number 17: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AN-A0XN-01A-21D-A107-01): tumor purity 0.47, ploidy 3.31, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,217 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:199,371,877–248,919,946, 1,143 genes, copy number 7 (broad region; genes not listed).
- chr2:103,874,310–104,733,362, 17 genes, copy number 7 (within-gene range 2–7): LINC01965, AC013727.3, AC096554.1, AHCYP3, AC068535.1, LINC01831, AC068535.2, LINC01102, LINC01103, AC013402.2, AC013402.3, AC068057.3, AC013402.1, RPL23AP27, AC068057.1, AC068057.2, SNORA72.
- chr2:154,286,589–206,796,189, 803 genes, copy number 7 (broad region; genes not listed).
- chr2:206,821,190–206,822,294, 1 gene, copy number 7: AC008269.2.
- chr2:207,239,864–207,529,795, 1 gene, copy number 7 (within-gene range 2–7): AC009226.1.
- chr2:207,529,737–208,057,745, 17 genes, copy number 7: CREB1, METTL21A, RPS29P9, LINC01857, RNU6-664P, PPP1R14BP2, Y_RNA, CCNYL1, AC096772.1, MIR4775, FZD5, PLEKHM3, AC083900.1, RNU6-360P, RPL9P14, RNA5SP116, RPL12P17.
- chr2:225,698,254–227,314,792, 13 genes, copy number 7 (within-gene range 5–7): AC016717.1, AC016717.2, AC016717.3, AC068138.1, AC062015.1, MIR5702, IRS1, AC010735.2, AC010735.1, RHBDD1, AC073149.1, COL4A4, COL4A3.
- chr5:58,198–19,142,346, 352 genes, copy number 8 (broad region; genes not listed).
- chr5:57,751,192–60,522,120, 20 genes, copy number 8 (within-gene range 2–8): AC106822.1, LINC02225, LINC02101, AC008786.1, PGAM1P1, PLK2, GAPT, AC008814.1, MIR548AE2, LINC02108, RAB3C, AC016642.1, RPL5P15, AC008852.1, PDE4D, AC092343.1, AC008833.1, NDUFB4P2, MIR582, AC034234.1.
- chr5:175,628,188–179,652,457, 143 genes, copy number 7–9 (broad region; genes not listed).
- chr6:56,843,928–58,438,364, 27 genes, copy number 7 (within-gene range 4–7): DST-AS1, RPL17P26, RNU6-626P, BEND6, OSTCP6, FTH1P15, MRPL30P1, KIAA1586, ZNF451, ZNF451-AS1, BAG2, RAB23, PRIM2, MIR548U, FO680682.1, AL021368.3, AL021368.5, AL021368.1, AL021368.2, GUSBP4, AL021368.4, POM121L14P, LINC00680, AL445250.1, GAPDHP15, AL390237.1, RBBP4P4.
- chr6:99,174,744–99,175,479, 1 gene, copy number 9: BDH2P1.
- chr6:101,181,257–102,070,083, 1 gene, copy number 9 (within-gene range 5–9): GRIK2.
- chr6:102,078,872–107,824,317, 60 genes, copy number 9–15: AP002530.1, AL357139.2, AL357139.1, Z98755.1, AL591387.1, AL590608.1, R3HDM2P2, NPM1P10, AL357522.1, AL356967.1, HACE1, RNU6-897P, AL357315.1, AL357315.2, LIN28B-AS1, LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3, PREP, AL133406.2, AL133406.1, RPL35P3, AL096794.1, LINC02836, Z97206.1, AL591518.1, RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12, SOBP, AL121957.1, AL096816.1, SCML4.
- chr8:37,421,341–42,796,392, 133 genes, copy number 16 (within-gene range 5–16) (broad region; genes not listed).
- chr8:98,371,228–98,942,827, 1 gene, copy number 7 (within-gene range 5–7): STK3.
- chr8:98,633,547–113,436,939, 220 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr11:95,976,598–110,464,884, 174 genes, copy number 9–17 (within-gene range 4–17) (broad region; genes not listed).
- chr18:62,715,541–62,980,433, 1 gene, copy number 7 (within-gene range 5–7): PHLPP1.
- chr18:63,123,346–65,125,710, 28 genes, copy number 7–9: BCL2, AC022726.1, AC022726.2, KDSR, AC036176.1, VPS4B, AC036176.2, SERPINB5, AC036176.3, ATP5MC1P6, SERPINB12, SERPINB13, SERPINB4, SERPINB11, SERPINB3, SERPINB7, SERPINB2, SERPINB10, HMSD, AC009802.1, SERPINB8, LINC01924, RPL12P39, LINC00305, LINC01538, AC027506.1, AC090348.1, AC007948.1.
- chr19:17,933,015–18,621,039, 46 genes, copy number 7: CCDC124, KCNN1, RNA5SP468, ARRDC2, AC020904.3, AC020904.2, AC020904.1, RPS18P13, IL12RB1, MAST3, AC007192.2, AC007192.1, PIK3R2, IFI30, MPV17L2, RAB3A, AC005759.1, AC008397.2, PDE4C, AC008397.1, IQCN, JUND, MIR3188, RPL39P38, LSM4, RN7SL513P, PGPEP1, GDF15, MIR3189, LRRC25, SSBP4, ISYNA1, AC010335.1, ELL, AC010335.2, AC010335.3, AC005387.1, FKBP8, AC005387.2, KXD1, AC005253.1, AC005253.2, UBA52, CRLF1, REX1BD, TMEM59L.
- chr20:60,087,826–61,940,617, 15 genes, copy number 7 (within-gene range 5–7): MIR646HG, MIR646, MTCO2P1, MIR4533, MIR548AG2, AL117372.1, AL139348.1, AL121910.1, LINC01718, CDH4, AL365229.1, BX640515.1, AL160412.1, AL162457.1, AL162457.2.

Autosomal genes at a single copy (total copy number 1): 985. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
